Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4861, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4861-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Status: Amend/

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

***** Addended Report *****

PATHOLOGIC DIAGNOSIS:

LEFT RADICAL NEPHRECTOMY:
(CLEAR CELL RENAL CELL CARCINOMA (8.2 cm), Fuhrman nuclear grade II/IV, arising in the lower pole with foci of tumor necrosis and hyalinization.
Approximately 60% of the tumor mass is viable.
Arterial, venous, and ureteral margins are negative for tumor.
Tumor is limited to the kidney and comes to within 0.1 cm of the Gerota's fascia margin.
No lymphovascular invasion is seen.
No venous invasion is seen.
Simple cortical cyst (1.3 cm).
The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.
AJCC Classification: T2 Nx MX.

CLINICAL DATA:

History: None given.
Operation: Left radical nephrectomy, regional lymph node dissection.
Operative Findings: None given.
Clinical Diagnosis: Left renal mass.

TISSUE SUBMITTED:

Left kidney with regional lymph nodes - FS room at 10:45, for special studies.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patients name, unit number, and "#1 Left kidney and regional lymph nodes", and consists of one 95.7 gram nephrectomy specimen (25.0 x 15.0 x 8.5 cm), including a kidney (13.0 x 7.2 x 6.0 cm), a ureter (8.5 cm in length x 0.3 cm in diameter), a renal vein (1.2 cm in length x 1.1 cm in diameter), and a renal artery (1.1 cm in length x 0.8 cm in diameter). In the lower pole is a well-circumscribed, golden/yellow tumor mass with areas of focal hemorrhage (6.0 x 8.2 x 5.0 cm). The tumor nodule appears limited to the kidney but distorts and expands the kidney into the perinephric fat. The tumor is present within 0.1 cm of the Gerota's fascial margin. No definitive features of invasion into the fat are identified. The tumor is 5.2 cm from the ureteral margin, 5.5 cm from the arterial margin, and 4.7 cm from the venous margin. There is also a blood-filled cyst (1.3 x 1.2 x 0.9 cm) in the upper pole, and the remainder of the renal parenchyma is tan/brown with well-defined corticomedullary junction. The pelvis and calices are covered by smooth, glistening mucosa. Representative sections of the tumor are sent to Cytogenetics and to Tissue Bank, and representative sections of normal kidney are saved for electron microscopy and IF and sent to Tissue Bank. No lymph node candidates are identified within the perinephric fat, and an adrenal gland is not present. Gross photographs are taken.

Micro A1: Arterial, venous and ureteral margins, 3 frags, [REDACTED]
Micro A2-A3: Tumor to Gerota's fascia, 2 frags, [REDACTED]
Micro A4-A5: Tumor, 2 frags, [REDACTED]
Micro A6: Tumor to normal kidney, 1 frag, [REDACTED]
Micro A7: Renal cyst, 1 frag, RSS.
Micro A8: Normal renal parenchyma, 1 frag, [REDACTED]

TCGA-CZ-4861

physician certifies that he/she

[page 2 of 4]
personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA

LEFT NEPHRECTOMY:

DIFFUSE AND NODULAR DIABETIC GLOMERULOSCLEROSIS, MODERATE, WITH SUPERIMPOSED COLLAPSING FEATURES (SEE NOTE)

MODERATELY ADVANCED SCLEROSING CHANGES OF THE KIDNEY:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (19 % OF GLOMERULI)
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (25% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, SEVERE (SEE NOTE)

PROMINENT CASTS IN DISTAL TUBULES (SEE NOTE)

NOTE:

The changes seen in this biopsy are those seen in patients with moderately advanced diabetic nephropathy. An independent and superimposed immune complex-mediated glomerulopathy has been ruled out. Also seen are superimposed collapsing lesions in few of the glomeruli. To put these morphological lesions in better perspective it is important to correlate this finding with the degree of proteinuria and renal failure in this patient. Collapsing lesions are sometimes present in patients with advanced kidney disease due to other causes; we have observed this type of lesions in a small percentage of end-stage kidneys removed during renal transplantation; the cause and mechanism of this type of lesions is poorly understood at this time. However, a superimposed collapsing glomerulopathy in this patient cannot be ruled out with certainty; patients with an active collapsing glomerulopathy can be expected to have a very pronounced proteinuria and renal functional impairment. It may therefore be prudent to determine the degree and the evolution of the proteinuria in this patient.

Prominent vascular sclerosis has traditionally been considered part of the structural changes seen in diabetic patients with renal disease. These vascular lesions are non-specific, however, and similar changes characterize various primary forms of vascular injury in the kidney. Such conditions include the healed phase of HUS/TTP and pro-coagulant states (thrombophilia, antiphospholipid antibody syndrome, etc.), autoimmune disorders (scleroderma, undifferentiated connective tissue disorders, etc.), toxic injury affecting components of the vascular wall (vero cytotoxin, antibody-mediated vascular injury, drugs with vascular toxicity, etc.), physical factors (irradiation, status post bone marrow transplantation), and, potentially, metabolic diseases with an important vascular component (gout, diabetes, hyperhomocysteinemia, etc.). Therefore, a primary form of vascular injury superimposed on diabetes mellitus should also be considered in the differential diagnosis of this patient's kidney disease.

The widespread cast formation in the distal tubules is worrisome. Although these casts appear to be benign hyaline cast in that they are PAS-positive, they do not appear fractured, they are not surrounded by a cell reaction, and they are reactive for polyclonal IgA on immunofluorescence microscopy, a prior episode of light chain cast nephropathy cannot be ruled out with absolute certainty especially since the casts stain slightly stronger for lambda than for kappa light chains. In my experience, myeloma casts lose their specific light chain reactivity with time and become hyaline casts; they transform from pure protein cast, which are characteristically PAS-negative, to conventional hyaline PAS-positive casts and, with time, they take on reactivity for

[page 3 of 4]
[REDACTED]

paraprotein in the serum and in the urine. I have to stress here, that the cast seen currently in this biopsy do not have the characteristics of classical myeloma casts.

The kidney parenchyma has been reviewed by Dr. [REDACTED] Renal Pathologist.

MICROSCOPIC DESCRIPTION:

The sample consists of renal cortex and outer medulla. There are two hundred and thirty four (234) glomeruli present in the sample submitted for light microscopy. Forty-four (44) glomeruli are globally obsolescent (sclerosed). The preserved glomeruli show enlargement of the glomerular tuft with diffuse sclerosis of the mesangium and increase of the mesangial cells. Several glomeruli show characteristic Kimmelstiel-Wilson nodules. Double contours are noted in some of the capillary loops with some glomeruli exhibiting signs of mesangiolysis. Focal reabsorption granules are also noted in two of the glomeruli with prominent epithelial cell proliferation and collapse of the capillary tufts. Tubules reveal marked thickening of the tubular basement membranes and focal tubular atrophy. PAS casts are seen. The interstitium is focally replaced by dense connective tissue, particularly in the areas of tubular atrophy. Approximately 25% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries reveal severe intimal sclerosis and duplication of the internal elastic lamina. Arterioles show hyaline deposits in the vessel walls of both afferent and efferent arterioles.

The integrity of the renal parenchyma and the structural details of the basement membranes were evaluated on sections stained with PAS, trichrome (AFOG), and Jones' silver methenamine.

IMMUNOFLUORESCENCE MICROSCOPY REPORT [REDACTED]

Sections of frozen tissue were incubated with antibodies specific for the heavy chains of IgG, IgA, and IgM, kappa and lambda light chains, C3, C1q, albumin, and fibrin-related antigens.

The sample consists of kidney cortex and medulla. There are fifty-one (51) glomeruli present, of which ten are globally sclerosed. There are no significant immune deposits present in the glomeruli. There is segmental, irregular granular deposition of IgM and C3 in the mesangial areas. Tubules contain reabsorbed proteins (albumin, IgG, C3) in the form of cytoplasmic granules. Tubular basement membranes reveal focal deposition of C3 (++/4+). Several casts in the distal tubules are reactive for polyclonal IgA with a noticeable overexpression of lambda over kappa light chains. Coarse IgM and C3 deposits are present in the walls of several arterioles. There is no difference noted in the intensity of the staining for kappa and lambda light chains in the background of the tissue.

[REDACTED]

This second addendum was added my mistake; no additional diagnostic information is added

[REDACTED]

[page 4 of 4]
Accession Number: [REDACTED]
Type: [REDACTED]
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist
[REDACTED]

Report Status: Final

KARYOTYPE: 46,XY[5]

METAPHASES COUNTED: 5

ANALYZED: 5

SCORED: 0

BANDING: GTG

INTERPRETATION:

Only 5 metaphase cells were obtained and analyzed from this specimen and no cytogenetic aberrations were identified. This limited/incomplete study may not rule out mosaicism at a level that is standard for such an analysis.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

Left Renal Mass

[REDACTED]

Source: NCI Genomic Data Commons file 420fd101-11ea-4041-8d08-b9c342463746 (TCGA-CZ-4861.C442C921-63CF-46F1-B28A-ACF01E5B2E2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).